TCGA case TCGA-CH-5762 — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Acinar Cell Neoplasms; Primary site: Prostate gland; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d4ffafdc-ee83-43df-aa3b-7326503c6438

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Acinar cell carcinoma: ICD-O-3 morphology code: 8550/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 60.4 years (22,068 days); Year of diagnosis: 2005; Method of diagnosis: Core Biopsy; AJCC clinical M: M0; AJCC pathologic T: T3b; AJCC pathologic N: N0; Primary gleason grade: Pattern 4; Secondary gleason grade: Pattern 3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Gleason score: 7.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 7; Zone of origin prostate: Peripheral zone.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (3 entries)
- Day 92 (initial diagnosis): Days to imaging: 92 days; Imaging type: Bone Scan, NOS; Imaging result: Negative.
- Day 92 (initial diagnosis): Days to imaging: 92 days; Imaging type: CT Scan; Imaging anatomic site: Abdomen / Pelvis; Imaging findings: No Evidence of Extraprostatic Extension.
- Follow-up contact recording only the day: day 1,339.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0.01 ng/mL (day 1,313).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CH-5762-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.4; Shortest dimension: 0.4.
  Slide TCGA-CH-5762-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-CH-5762-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 25; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-CH-5762-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CH-5762-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 0.4; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Method initial path diagnosis: Core needle biopsy; Bone scan results: Normal (no evidence of prostate cancer) [cM0]; Ct scan ab pelvis indicator: Yes; Diagnostic mri performed: No; Lymph nodes examined: Yes; Biochemical recurrence indicator: No.
- Stage record, Psa: PSA most recent results: .01.
- Stage record, Gleason grading: Gleason pattern primary: 4; Gleason pattern secondary: 3.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,339 days; disease-specific survival: no event (censored), 1,339 days; disease-free interval: no event (censored), 1,339 days; progression-free interval: no event (censored), 1,339 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CH-5762-01A-11D-1574-01): tumor purity 0.34, ploidy 2.03, whole-genome doublings 0.
